Somatic mutation profile of tumor specimen TARGET-20-PARCEV-09A (aliquot TARGET-20-PARCEV-09A-01D) from TARGET case TARGET-20-PARCEV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.4 years (4,152 days).
Specimen TARGET-20-PARCEV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f65f11ec-53e1-451e-a43d-13a30bd687a9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCEV-14A (Bone Marrow Normal), aliquot TARGET-20-PARCEV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e08b1a3-fd2f-44da-85b6-a157d6704600

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1104dup p.S369Vfs*4 | Frame Shift Ins (INS) | VAF 85/244 reads (35%) | catalogued as COSV60065450, COSV60070013, COSV60076917, COSV99070067; called by mutect2, pindel, varscan2
- HDAC9 | c.2577+30T>C | Intron (SNP) | VAF 112/237 reads (47%) | called by muse, mutect2
- HDAC9 | c.2577+32A>T | Intron (SNP) | VAF 113/240 reads (47%) | called by muse, mutect2
